Somatic mutation profile of cancer-model specimen HCM-BROD-1119-C43-85B (Adherent Cell Line, passage 8; aliquot HCM-BROD-1119-C43-85B-01D-A87L-36), derived from the metastatic tumor of HCMI case HCM-BROD-1119-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Eye, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.0 years (26,307 days).
Specimen HCM-BROD-1119-C43-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a087526f-38d8-4bc9-8011-6b4d3e88d895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1119-C43-10A (Blood Derived Normal), aliquot HCM-BROD-1119-C43-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe690ab8-e316-47ad-9154-08f2db6814e0

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 102/216 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GSE1 | c.661A>G p.S221G | Missense Mutation (SNP) | VAF 284/534 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1260019045; called by muse, mutect2, varscan2
- KRT85 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs549707125, COSV57736489; called by muse, mutect2, varscan2
- PIEZO1 | c.7081C>T p.R2361C | Missense Mutation (SNP) | VAF 173/388 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs980506949, COSV56342489; called by muse, mutect2, varscan2
- RTN1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 253/529 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV50718415; called by muse, mutect2, varscan2
- ASH1L | c.3101G>C p.G1034A | Missense Mutation (SNP) | VAF 187/464 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ATL3 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 224/481 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- BAHD1 | c.311del p.P104Hfs*104 | Frame Shift Del (DEL) | VAF 313/775 reads (40%) | called by mutect2, pindel, varscan2
- DEFA3 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 89/558 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MYRFL | c.2626C>A p.H876N | Missense Mutation (SNP) | VAF 265/568 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRPD | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 201/447 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF324 | c.198C>G p.D66E | Missense Mutation (SNP) | VAF 183/394 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DLEC1 | c.1569C>T p.F523= | Silent (SNP) | VAF 182/369 reads (49%) | called by muse, mutect2, varscan2
- NPR1 | c.18C>A p.R6= | Silent (SNP) | VAF 274/545 reads (50%) | called by muse, mutect2, varscan2
- OLFML2A | c.699C>T p.I233= | Silent (SNP) | VAF 197/431 reads (46%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-4917C>T | Intron (SNP) | VAF 14/497 reads (3%) | called by muse, mutect2
